Somatic mutation profile of tumor specimen 0DAS6J from CCDI case PBBKHR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 8.1 years (2,966 days).
Specimen 0DAS6J: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98e09484-0ac3-405f-bad2-cbbb341887d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAS6K (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/528bebf9-f57b-41e3-b6cd-86ff6e091dfa

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGF2BP1 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754194926; called by muse, mutect2
- LRRC9 | c.2447T>C p.L816P | Missense Mutation (SNP) | VAF 82/225 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777033789; called by muse, mutect2, varscan2
- HCAR2 | c.608T>A p.I203N | Missense Mutation (SNP) | VAF 34/366 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- ITPR3 | c.1426C>T p.L476= | Silent (SNP) | VAF 43/594 reads (7%) | called by muse, mutect2
- KMT5C | c.1299C>T p.L433= | Silent (SNP) | VAF 20/322 reads (6%) | catalogued as rs764786236, COSV55320538; called by muse, mutect2
- GLYATL1 | c.78+17A>G | Intron (SNP) | VAF 13/222 reads (6%) | catalogued as rs1350985513; called by muse, mutect2
- TEX10 | c.2466-52C>T | Intron (SNP) | VAF 20/92 reads (22%) | called by muse, mutect2, varscan2
